Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19P, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19P-06A (Metastatic).

1CD-0-3

Melanoma, NOS 8720/3 12/15/10 *hw*

Site code: groin, soft tissue C49.5

PATIENT HISTORY:

No clinical history is given.

PRE-OP DIAGNOSIS: Right inguinal mass.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Excision groin mass.

FINAL DIAGNOSIS:

SOFT TISSUE, LYMPH NODE, RIGHT GROIN, EXCISION -

MALIGNANT TUMOR CONSISTENT WITH METASTATIC MELANOMA IN ONE LYMPH NODE WITH FOCAL EXTRACAPSULAR SPREAD, 5CM. (see comment).

Source: NCI Genomic Data Commons file 9a000bbf-75c9-467a-a0be-713dc1234010 (TCGA-ER-A19P.555A37D4-F9BD-4CC2-8AC3-B3525FCE9A4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).